Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A7B0, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A7B0-01A (Primary Tumor).

[page 1 of 3]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) LEFT PELVIC LYMPH NODES:
Five lymph nodes, no tumor present (0/5).
(B) RIGHT PELVIC LYMPH NODES:
Twelve lymph nodes, no tumor present (0/12).
(C) PROSTATE AND SEMINAL VESICLES;
Supplemental report to follow.

CLF ICD-O-3
Adenocarcinoma, acinar
path 8/40/13
Adenocarcinoma NOS
8/40/13
State Prostate NOS
C61.9
JW 8/22/13

Entire report and diagnosis completed by

GROSS DESCRIPTION

- (A) LEFT PELVIC LYMPH NODES – One pale gray fibroadipose tissue (7.0 x 3.8 x 1.5 cm) with multiple possible lymph nodes ranging from 0.3 x 0.3 x 0.4 cm to 3.5 x 1.7 x 1.2 cm. The lymph nodes are entirely submitted.
SECTION CODE: A1, three possible lymph nodes; A2, two possible lymph nodes; A3, one possible lymph node, serially sectioned; A4-A6, one possible lymph node, serial sectioned.
(B) RIGHT PELVIC LYMPH NODE, PERMANENT – Two fragments of pale gray fibroadipose tissue (7.0 x 4.0 x 2.5 cm, in aggregate) with multiple possible lymph nodes ranging from 0.4 x 0.3 x 0.3 cm to 2.2 x 1.4 x 0.7 cm. The lymph nodes are entirely submitted.
SECTION CODE: B1, three possible lymph nodes; B2, three possible lymph nodes; B3, two possible lymph nodes; B4-B7, each contain one possible lymph node, serial sectioned; B8, B9, one possible lymph node, serial sectioned.
(C) PROSTATE AND SEMINAL VESICLES – Supplemental report to follow.

CLINICAL HISTORY

Prostate cancer.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."
Entire report and diagnosis completed by:

These tests have not been

Start of ADDENDUM

[page 2 of 3]
Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

(C) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA, GLEASON SCORE 9 (4+5). (SEE COMMENT)

TUMOR EXTENDING FOCALLY INTO EXTRAPROSTATIC TISSUE.

TUMOR INVADING RIGHT AND LEFT SEMINAL VESICLES.

Margins of resection free of tumor.

PERINEURAL INVASION PRESENT.

No lymphovascular invasion identified.

Segments of right and left vasa deferentia, no tumor present.

COMMENT

The prostate gland contains two foci of prostatic adenocarcinoma, one in the peripheral zone and one in the transition zone. The dominant tumor focus is located in the left anterior, left anterolateral, left lateral, left posterolateral, left posterior, mid posterior, and right posterior peripheral zone with extension into the left and right transition zone. This tumor focus measures 2.5 x 2.0 cm in the largest cross-sectional dimension and it is present in the two cross sections of the prostate and extensively in the apex and base. The tumor exhibits extraprostatic extension on the left anterior surface of the prostate, left posterolateral surface and left superior neurovascular bundle region. The added length of extraprostatic extension is 5.5 mm. The margins of resection are free of tumor. The tumor invades the right (intraprostatic) and left (intraprostatic and extraprostatic portions) seminal vesicles. The margins of resection are free of tumor. The second tumor focus is located in the right transition zone. This tumor focus measures 1.0 x 0.4 cm in the largest cross-sectional dimension and it is present in the two cross sections of the prostate and focally in the apex and base. This tumor focus is of lower histologic grade and confined to the prostate. All margins of resection are free of tumor.

GROSS DESCRIPTION

(C) PROSTATE AND SEMINAL VESICLES – A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (5.2 x 3.0 x 4.5 cm, 42 grams, post-fixation) has the usual shape. The soft tissue present along the left posterolateral aspect of the prostate is abundant and more extensive than along the right side. A nodule is palpated on the left side of the prostate. Serial cross sections after fixation demonstrate areas consistent with tumor in the right peripheral zone of the two cross sections of the prostate and in the right anterolateral peripheral zone of the second cross section.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

SECTION CODE: C1-C3, right seminal vesicle and segment of right vas deferens from the base towards the tip; C4-C7, left seminal vesicle and segment of left vas deferens from the base towards the tip; C8, C9, prostatic base, right border; C10-C14,

[page 3 of 3]
Specimen Date/Time:

prostatic base, right posterior border; C15-C24, prostatic base, central portion; C25, C26, prostatic base, left border; C27, C28, prostatic base, left posterior border; C29-C31, apex anterior; C32-C34, apex left; C35-C37, apex posterior; C38-C39, apex right; C40, detached portions of margin of resection according to the specimen radiograph; C41-C50, sections of the two cross sections of the prostate according to the specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black. Orange ink (C43 and 44) denote surfaces that do not represent the true margin of resection.

SNOMED CODES

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 42669caf-1091-4718-ba39-970b4eb4c0a1 (TCGA-KK-A7B0.A6F717F0-66D2-4AEB-88F6-1A95D26489BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).